Somatic mutation profile of tumor specimen ALCH-B3CR-TTP1-A (aliquot ALCH-B3CR-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B3CR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 50.9 years (18,583 days).
Specimen ALCH-B3CR-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 444a67a5-9c0b-4459-b876-7a2fb266c9c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3CR-NB1-A (Blood Derived Normal), aliquot ALCH-B3CR-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a504345-41a5-46c5-9559-99e9bfff2144

The open-access MAF lists 312 somatic variants for this specimen: 213 protein-altering or splice-affecting, 51 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 186, Silent 51, Intron 18, Nonsense Mutation 13, RNA 11, 5'UTR 8, 3'UTR 6, Splice Site 5, Frame Shift Del 5, 5'Flank 4, Splice Region 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP6 | c.2669G>A p.W890* | Nonsense Mutation (SNP) | VAF 364/694 reads (52%) | catalogued as rs1555108264; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.1558G>A p.G520S | Missense Mutation (SNP) | VAF 64/106 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs766013726, COSV54027975; called by muse, mutect2, varscan2
- ALDH1L1 | c.572T>A p.L191H | Missense Mutation (SNP) | VAF 141/289 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as rs775853640; called by muse, mutect2, varscan2
- ASIC2 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 89/283 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV56763704; called by muse, mutect2, varscan2
- ATP4A | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 158/1225 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.967); catalogued as rs567483940, COSV52867667; called by muse, mutect2, varscan2
- BRINP3 | c.1909G>T p.G637C | Missense Mutation (SNP) | VAF 522/600 reads (87%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV66516533, COSV66525950; called by muse, mutect2, varscan2
- C6orf118 | c.304G>T p.V102L | Missense Mutation (SNP) | VAF 78/102 reads (76%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as rs1276465931; called by muse, mutect2, varscan2
- CADPS | c.1951C>A p.P651T | Missense Mutation (SNP) | VAF 91/105 reads (87%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV51883133, COSV51900613; called by muse, mutect2, varscan2
- CES1 | c.403-1G>A p.X135_splice | Splice Site (SNP) | VAF 113/555 reads (20%) | catalogued as rs1278230457; called by muse, mutect2, varscan2
- CGN | c.2210G>T p.R737L | Missense Mutation (SNP) | VAF 321/366 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99642976; called by muse, mutect2, varscan2
- CIPC | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 85/216 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324862610; called by muse, mutect2, varscan2
- CRTC1 | c.1747G>T p.G583W | Missense Mutation (SNP) | VAF 178/306 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58724018; called by muse, mutect2, varscan2
- CTNND2 | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 234/394 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV100476157; called by muse, mutect2, varscan2
- DPPA4 | c.511C>G p.P171A | Missense Mutation (SNP) | VAF 310/828 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.098); catalogued as COSV59512646; called by muse, varscan2
- DROSHA | c.3572C>A p.A1191E | Missense Mutation (SNP) | VAF 222/411 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60778959; called by muse, mutect2, varscan2
- DTHD1 | c.1356G>T p.W452C (on ENST00000456874; = p.W287C on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 149/199 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs968579799; called by muse, mutect2, varscan2
- EPHA5 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1458893557, COSV56668549; called by muse, mutect2, varscan2
- FAM135B | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 114/477 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50522898; called by muse, mutect2, varscan2
- GCN1 | c.3589G>T p.V1197F | Missense Mutation (SNP) | VAF 93/351 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56110713; called by muse, mutect2, varscan2
- GLRA3 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 120/153 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as rs765420954, COSV99927339; called by muse, mutect2, varscan2
- GRIN1 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 134/267 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV59301425; called by muse, mutect2, varscan2
- HGF | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 152/202 reads (75%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1228314400, COSV55958402; called by muse, mutect2, varscan2
- IFNA4 | c.374A>T p.Q125L | Missense Mutation (SNP) | VAF 193/589 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as rs1457506136; called by muse, mutect2, varscan2
- KCNJ3 | c.53C>A p.S18* | Nonsense Mutation (SNP) | VAF 127/279 reads (46%) | catalogued as COSV54534411; called by muse, mutect2, varscan2
- KMT2D | c.15176A>T p.H5059L | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM114145; called by muse, mutect2, varscan2
- MAGEA6 | c.461C>A p.A154D | Missense Mutation (SNP) | VAF 364/388 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782563714; called by muse, mutect2, varscan2
- MON2 | c.2125G>T p.V709L | Missense Mutation (SNP) | VAF 79/282 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs760639913; called by mutect2, varscan2
- MUC5B | c.4156C>T p.P1386S | Missense Mutation (SNP) | VAF 107/139 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1427795473; called by muse, mutect2, varscan2
- MYH1 | c.5098G>T p.E1700* | Nonsense Mutation (SNP) | VAF 288/404 reads (71%) | catalogued as COSV56857025; called by muse, mutect2, varscan2
- MYH4 | c.5596C>A p.L1866I | Missense Mutation (SNP) | VAF 96/127 reads (76%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV55116433; called by muse, mutect2, varscan2
- MYOM2 | c.831C>A p.D277E | Missense Mutation (SNP) | VAF 131/163 reads (80%) | SIFT tolerated (0.9); PolyPhen benign (0.177); catalogued as rs749365756; called by muse, mutect2, varscan2
- NOS3 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 132/167 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52492577; called by muse, mutect2, varscan2
- NTRK1 | c.698A>G p.E233G | Missense Mutation (SNP) | VAF 154/402 reads (38%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.466); catalogued as rs1394944314; called by muse, varscan2
- NXF5 | n.1440G>T | Splice Region (SNP) | VAF 277/326 reads (85%) | catalogued as COSV99534440; called by muse, mutect2, varscan2
- OGFOD2 | c.413G>T p.R138L (on ENST00000228922 / NM_001304833.1; = p.R78L on NM_024623.3) | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as COSV57441911; called by muse, mutect2, varscan2
- OR11H4 | c.542del p.P181Lfs*14 | Frame Shift Del (DEL) | VAF 93/255 reads (36%) | catalogued as COSV59559761; called by mutect2, pindel, varscan2
- OR2T2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 360/969 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370402767; called by muse, mutect2, varscan2
- OR52E6 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 48/62 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766523236; called by muse, mutect2
- OR5AN1 | c.914T>A p.L305* | Nonsense Mutation (SNP) | VAF 25/33 reads (76%) | catalogued as COSV58321664; called by muse, varscan2
- PCDHGB1 | c.2192C>G p.S731C | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV53982552; called by muse, mutect2, varscan2
- PKP4 | c.3047C>G p.S1016W | Missense Mutation (SNP) | VAF 206/261 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs749238207; called by muse, mutect2, varscan2
- PLXNC1 | c.2021C>A p.T674K | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51569438; called by muse, mutect2, varscan2
- POLE2 | c.43A>T p.K15* | Nonsense Mutation (SNP) | VAF 218/470 reads (46%) | catalogued as rs1172197561; called by muse, mutect2, varscan2
- POM121L2 | c.2227C>G p.P743A | Missense Mutation (SNP) | VAF 189/242 reads (78%) | SIFT tolerated (0.39); PolyPhen benign (0.085); catalogued as rs1459830350; called by muse, mutect2, varscan2
- PPFIA2 | c.3352C>G p.Q1118E | Missense Mutation (SNP) | VAF 81/321 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.865); catalogued as COSV100335591; called by muse, mutect2, varscan2
- RB1 | c.368dup p.N123Kfs*8 | Frame Shift Ins (INS) | VAF 134/242 reads (55%) | catalogued as rs869214358; called by mutect2, pindel, varscan2
- RGS20 | c.194C>A p.S65* | Nonsense Mutation (SNP) | VAF 275/1000 reads (28%) | catalogued as COSV99033239; called by muse, mutect2, varscan2
- RUNX1T1 | c.1462C>A p.R488S (on ENST00000265814 / NM_001198628.1; = p.R461S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 404/693 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.44); catalogued as rs770002524, COSV56137763, COSV56148522; called by muse, mutect2, varscan2
- SCN10A | c.5551G>A p.E1851K | Missense Mutation (SNP) | VAF 242/278 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs947319524; called by muse, mutect2, varscan2
- SENP6 | c.2876G>A p.G959E | Missense Mutation (SNP) | VAF 86/112 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64188351; called by muse, mutect2, varscan2
- SI | c.4397C>T p.P1466L | Missense Mutation (SNP) | VAF 107/407 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52264717; called by muse, mutect2, varscan2
- SLC3A1 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 284/635 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99577784; called by muse, mutect2, varscan2
- SLCO1B3 | c.85-1G>A p.X29_splice | Splice Site (SNP) | VAF 77/328 reads (23%) | catalogued as rs755205344; called by muse, mutect2, varscan2
- SLITRK2 | c.196C>G p.Q66E | Missense Mutation (SNP) | VAF 141/237 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV59424320; called by muse, mutect2, varscan2
- SLITRK3 | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV53853209; called by muse, mutect2, varscan2
- SOX17 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 113/361 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs1489973933, COSV52024154; called by muse, mutect2, varscan2
- TEX44 | c.883G>C p.V295L | Missense Mutation (SNP) | VAF 183/228 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58354682; called by muse, mutect2, varscan2
- TPO | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 111/282 reads (39%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.451); catalogued as rs758227035; called by muse, mutect2, varscan2
- TREX2 | c.207G>T p.E69D (on ENST00000334497; = p.E26D on NM_080701.3) | Missense Mutation (SNP) | VAF 60/65 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs1556979490; called by muse, mutect2, varscan2
- TRIM28 | c.2384G>T p.R795L | Missense Mutation (SNP) | VAF 197/256 reads (77%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV53399640; called by muse, mutect2, varscan2
- TRIM51GP | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 196/232 reads (84%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs188284786; called by muse, mutect2, varscan2
- TRPM6 | c.3852G>T p.R1284S | Missense Mutation (SNP) | VAF 206/493 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs1475676841; called by muse, mutect2, varscan2
- USH2A | c.7787A>G p.Y2596C | Missense Mutation (SNP) | VAF 489/545 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs371685066; called by muse, mutect2, varscan2
- VASH1 | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV51335171; called by muse, mutect2, varscan2
- XRCC4 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.509); catalogued as rs372493882; called by muse, varscan2
- ZBED9 | c.1172G>T p.R391I | Missense Mutation (SNP) | VAF 42/56 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as rs1253581700; called by muse, mutect2, varscan2
- ZBTB8B | c.1454A>T p.Q485L | Missense Mutation (SNP) | VAF 90/108 reads (83%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1314838116; called by muse, mutect2, varscan2
- ABCC12 | c.316C>A p.P106T | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AC100868.1 | c.716G>T p.S239I | Missense Mutation (SNP) | VAF 113/508 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ADAMTS18 | c.2865G>C p.K955N | Missense Mutation (SNP) | VAF 274/680 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AGBL4 | c.1216A>G p.S406G | Missense Mutation (SNP) | VAF 265/361 reads (73%) | SIFT tolerated (0.87); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ANHX | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- ANKS1A | c.2296G>T p.G766C | Missense Mutation (SNP) | VAF 142/176 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKS1B | c.2673G>C p.E891D (on ENST00000547776 / NM_152788.4; = p.E117D on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- ANTXRL | c.1133A>G p.Q378R | Missense Mutation (SNP) | VAF 180/224 reads (80%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANXA6 | c.1883C>A p.S628Y | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP002748.5 | c.1226C>G p.A409G | Missense Mutation (SNP) | VAF 244/341 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF10 | c.3611C>A p.S1204Y (on ENST00000398564; = p.S1179Y on NM_014629.4) | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARID2 | c.4775A>G p.N1592S | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARL11 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 182/248 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ATG2B | c.801C>G p.H267Q | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ATRX | c.4351G>C p.E1451Q | Missense Mutation (SNP) | VAF 149/177 reads (84%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BCO1 | c.269T>A p.V90E | Missense Mutation (SNP) | VAF 163/429 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BIRC5 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 75/109 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C8orf48 | c.170G>T p.R57M | Missense Mutation (SNP) | VAF 161/219 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- CA10 | c.179G>T p.C60F | Missense Mutation (SNP) | VAF 99/413 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC102B | c.84C>A p.D28E | Missense Mutation (SNP) | VAF 327/422 reads (77%) | SIFT tolerated (0.4); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCDC141 | c.1337G>T p.C446F | Missense Mutation (SNP) | VAF 205/866 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CCDC85B | c.320G>C p.R107P | Missense Mutation (SNP) | VAF 63/86 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- CFAP221 | c.1411G>T p.V471F | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CFC1 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 177/778 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); called by muse, varscan2
- CHRNA1 | c.275T>A p.L92* | Nonsense Mutation (SNP) | VAF 274/690 reads (40%) | called by muse, mutect2, varscan2
- CLEC4A | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 84/392 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CLMP | c.367C>G p.H123D | Missense Mutation (SNP) | VAF 197/267 reads (74%) | SIFT tolerated (0.18); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- COL19A1 | c.1483-2A>T p.X495_splice | Splice Site (SNP) | VAF 110/152 reads (72%) | called by muse, varscan2
- COL5A2 | c.2914G>T p.G972* | Nonsense Mutation (SNP) | VAF 159/410 reads (39%) | called by muse, mutect2, varscan2
- CPA1 | c.476T>G p.V159G | Missense Mutation (SNP) | VAF 123/151 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPA5 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 129/151 reads (85%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPQ | c.862A>T p.S288C | Missense Mutation (SNP) | VAF 186/579 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CYP4B1 | c.1471G>T p.V491F | Missense Mutation (SNP) | VAF 274/378 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- DMD | c.5923C>A p.H1975N | Missense Mutation (SNP) | VAF 48/55 reads (87%) | SIFT tolerated (0.2); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- DPP10 | c.2257-1G>T p.X753_splice | Splice Site (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2
- EIF5B | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 230/551 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EMILIN2 | c.2218T>C p.C740R | Missense Mutation (SNP) | VAF 372/669 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- EYS | c.1372C>G p.L458V | Missense Mutation (SNP) | VAF 159/197 reads (81%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FABP1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 143/385 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FAM135B | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FASTKD3 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 195/359 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FMN2 | c.47T>C p.L16S | Missense Mutation (SNP) | VAF 61/74 reads (82%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMN2 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 124/150 reads (83%) | SIFT tolerated, low confidence (0.19); called by muse, mutect2, varscan2
- FREM1 | c.5900G>A p.R1967K | Missense Mutation (SNP) | VAF 91/290 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FRMPD1 | c.1511G>C p.G504A | Missense Mutation (SNP) | VAF 198/488 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- GALNT13 | c.469A>T p.S157C | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GEN1 | c.818A>C p.H273P | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- GGA1 | c.101G>A p.C34Y | Missense Mutation (SNP) | VAF 253/663 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GH2 | c.455G>A p.W152* | Nonsense Mutation (SNP) | VAF 167/316 reads (53%) | called by muse, mutect2, varscan2
- GIT1 | c.1649del p.P550Lfs*67 | Frame Shift Del (DEL) | VAF 62/261 reads (24%) | called by mutect2, pindel, varscan2
- GLE1 | c.839A>T p.Q280L | Missense Mutation (SNP) | VAF 276/727 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GOLGA6L2 | c.788C>G p.P263R | Missense Mutation (SNP) | VAF 84/152 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGA6L6 | c.1194G>T p.K398N | Missense Mutation (SNP) | VAF 131/811 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- GRIN2B | c.2320C>A p.R774S | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- GRIN2C | c.1814T>A p.L605Q | Missense Mutation (SNP) | VAF 130/465 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIN2C | c.1092C>G p.N364K | Missense Mutation (SNP) | VAF 120/230 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- GRIP1 | c.1501C>T p.P501S (on ENST00000359742 / NM_001379345.1; = p.P449S on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/503 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HCN1 | c.1838T>A p.V613D | Missense Mutation (SNP) | VAF 131/438 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- HOXA13 | c.724del p.H242Tfs*93 | Frame Shift Del (DEL) | VAF 183/803 reads (23%) | called by mutect2, pindel, varscan2
- HOXD3 | c.845A>G p.Y282C | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- KDM6A | c.2534A>T p.N845I | Missense Mutation (SNP) | VAF 72/85 reads (85%) | SIFT tolerated (0.06); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- KIAA1328 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 154/186 reads (83%) | called by muse, mutect2, varscan2
- KMT2B | c.3164G>T p.R1055L | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KNDC1 | c.1708C>G p.R570G | Missense Mutation (SNP) | VAF 94/122 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMA2 | c.4175A>C p.E1392A | Missense Mutation (SNP) | VAF 402/500 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LIMA1 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- LINGO4 | c.1100T>C p.L367P | Missense Mutation (SNP) | VAF 144/349 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LOXHD1 | c.6608C>G p.T2203R (on ENST00000642948; = p.T2141R on NM_144612.7) | Missense Mutation (SNP) | VAF 532/668 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LRRK2 | c.5707G>T p.V1903L | Missense Mutation (SNP) | VAF 129/472 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MASP1 | c.1338G>A p.M446I | Missense Mutation (SNP) | VAF 140/559 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED12L | c.5630A>T p.Q1877L | Missense Mutation (SNP) | VAF 797/1435 reads (56%) | SIFT tolerated, low confidence (0.93); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MKRN3 | c.885A>T p.K295N | Missense Mutation (SNP) | VAF 100/338 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MNDA | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 179/223 reads (80%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MS4A14 | c.1863C>A p.F621L | Missense Mutation (SNP) | VAF 210/257 reads (82%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- MS4A3 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 163/214 reads (76%) | SIFT tolerated (0.13); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- NAALADL2 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 93/403 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NCKAP1 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 134/395 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NEK10 | c.3415-1G>T p.X1139_splice | Splice Site (SNP) | VAF 79/95 reads (83%) | called by muse, varscan2
- NEK10 | c.2211G>T p.L737F | Missense Mutation (SNP) | VAF 83/104 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NKAIN1 | c.54G>T p.L18= | Splice Region (SNP) | VAF 57/74 reads (77%) | called by muse, mutect2, varscan2
- NLGN1 | c.2369G>A p.G790E | Missense Mutation (SNP) | VAF 81/828 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NOD2 | c.935del p.L312Rfs*65 | Frame Shift Del (DEL) | VAF 148/573 reads (26%) | called by mutect2, pindel, varscan2
- NR3C1 | c.1906C>G p.L636V | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- NTNG1 | c.530A>G p.Y177C | Missense Mutation (SNP) | VAF 87/111 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NTRK1 | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 156/402 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.086); called by muse, varscan2
- OGFR | c.1064C>A p.A355E | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OLA1 | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 194/472 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- OR2Z1 | c.7del p.D3? | Frame Shift Del (DEL) | VAF 51/100 reads (51%) | called by mutect2, pindel, varscan2
- OR4F15 | c.448A>T p.I150F | Missense Mutation (SNP) | VAF 121/238 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR4Q2 | c.585dup p.E196* | Frame Shift Ins (INS) | VAF 188/513 reads (37%) | called by mutect2, pindel, varscan2
- OR5H6 | c.402G>T p.M134I (on ENST00000642105; = p.M118I on NM_001005479.2) | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, varscan2
- OR6C1 | c.866G>C p.S289T | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, varscan2
- OTOL1 | c.1189A>T p.R397W | Missense Mutation (SNP) | VAF 170/309 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PACRG | c.661C>A p.R221S | Missense Mutation (SNP) | VAF 139/173 reads (80%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDH11X | c.923T>A p.L308H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PCDHGA7 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PHF20L1 | c.1921G>T p.V641L | Missense Mutation (SNP) | VAF 111/183 reads (61%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITPNM3 | c.1468G>T p.G490C | Missense Mutation (SNP) | VAF 51/61 reads (84%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PKP4 | c.2932C>G p.L978V | Missense Mutation (SNP) | VAF 229/282 reads (81%) | SIFT tolerated (0.69); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PLEKHA7 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 228/293 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- PPARD | c.607G>C p.G203R | Missense Mutation (SNP) | VAF 121/156 reads (78%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- PPP2R2D | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 146/200 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- PRAG1 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 156/215 reads (73%) | called by muse, mutect2, varscan2
- PRDM9 | c.1044G>T p.R348S | Missense Mutation (SNP) | VAF 357/735 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRMT9 | c.2533C>A p.Q845K | Missense Mutation (SNP) | VAF 149/189 reads (79%) | SIFT tolerated (0.3); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PTPRK | c.1810G>T p.A604S | Missense Mutation (SNP) | VAF 86/118 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.048); called by muse, varscan2
- RESF1 | c.1146A>C p.Q382H | Missense Mutation (SNP) | VAF 94/190 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SCNN1G | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 138/409 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SEMA5A | c.2256G>C p.M752I | Missense Mutation (SNP) | VAF 136/457 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- SEMA5B | c.1799C>A p.A600D | Missense Mutation (SNP) | VAF 108/419 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SLC22A6 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 238/314 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- SLC44A1 | c.1127A>T p.K376I | Missense Mutation (SNP) | VAF 177/366 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SLC49A4 | c.1340G>T p.W447L | Missense Mutation (SNP) | VAF 128/416 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC49A4 | c.1341G>C p.W447C | Missense Mutation (SNP) | VAF 129/420 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC4A3 | c.2375G>A p.G792D | Missense Mutation (SNP) | VAF 95/115 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SLC6A12 | c.1032G>A p.M344I | Missense Mutation (SNP) | VAF 140/295 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC6A3 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 287/495 reads (58%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SNURF | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 213/973 reads (22%) | called by muse, mutect2, varscan2
- SPATA7 | c.951A>G p.I317M | Missense Mutation (SNP) | VAF 145/328 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- STK31 | c.2424G>C p.M808I | Missense Mutation (SNP) | VAF 80/340 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SYCP2 | c.3976C>T p.H1326Y | Missense Mutation (SNP) | VAF 74/143 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TBC1D22B | c.1464G>T p.E488D | Missense Mutation (SNP) | VAF 221/292 reads (76%) | SIFT tolerated (0.11); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TDRD5 | c.1594T>C p.C532R | Missense Mutation (SNP) | VAF 159/388 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM200A | c.809G>T p.S270I | Missense Mutation (SNP) | VAF 72/92 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TNFRSF11A | c.275G>T p.C92F | Missense Mutation (SNP) | VAF 154/188 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- TRAV8-4 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- TRIM45 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 193/236 reads (82%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- TSPAN19 | c.613A>C p.S205R | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- TTC21B | c.2971C>G p.R991G | Missense Mutation (SNP) | VAF 163/211 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC13B | c.3794T>C p.V1265A | Missense Mutation (SNP) | VAF 147/346 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- UNC13C | c.4289C>G p.S1430C | Missense Mutation (SNP) | VAF 74/350 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- VGLL3 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 204/260 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- VPS41 | c.297G>T p.M99I | Missense Mutation (SNP) | VAF 185/452 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS41 | c.296T>A p.M99K | Missense Mutation (SNP) | VAF 186/453 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- WASF3 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 137/174 reads (79%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WASHC4 | c.2626A>G p.I876V | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, varscan2
- WDR64 | c.192T>A p.F64L | Missense Mutation (SNP) | VAF 124/358 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XKR3 | c.1080G>T p.L360F | Missense Mutation (SNP) | VAF 134/340 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, varscan2
- ZC4H2 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 75/82 reads (91%) | called by muse, mutect2, varscan2
- ZEB1 | c.2957G>C p.C986S | Missense Mutation (SNP) | VAF 206/270 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZFAND4 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ZFHX4 | c.1330A>T p.N444Y | Missense Mutation (SNP) | VAF 131/394 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZFHX4 | c.7079T>A p.V2360E | Missense Mutation (SNP) | VAF 84/320 reads (26%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZIC1 | c.896A>T p.E299V | Missense Mutation (SNP) | VAF 118/621 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF138 | c.584A>G p.Y195C (on ENST00000307355 / NM_001367572.1; = p.Y169C on NM_006524.4) | Missense Mutation (SNP) | VAF 81/198 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF513 | c.400G>T p.G134W | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ANK2 | c.2421C>T p.I807= | Silent (SNP) | VAF 533/661 reads (81%) | catalogued as rs554153174, COSV52154571; called by muse, mutect2, varscan2
- AP2A1 | c.630C>T p.L210= | Silent (SNP) | VAF 160/229 reads (70%) | called by muse, mutect2, varscan2
- APOB | c.6396G>A p.E2132= | Silent (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- APOBR | c.2523G>A p.E841= (on ENST00000431282; = p.E850= on NM_018690.4) | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV60491357; called by muse, varscan2
- ASB3 | c.1437A>G p.L479= | Silent (SNP) | VAF 128/314 reads (41%) | catalogued as rs1263442476; called by muse, varscan2
- ATPSCKMT | c.480C>T p.F160= | Silent (SNP) | VAF 168/352 reads (48%) | catalogued as rs758685178; called by muse, mutect2, varscan2
- CPA6 | c.1227C>A p.L409= | Silent (SNP) | VAF 149/585 reads (25%) | called by muse, mutect2, varscan2
- CPAMD8 | c.4776G>A p.A1592= (on ENST00000651564; = p.A1545= on NM_015692.5) | Silent (SNP) | VAF 108/320 reads (34%) | catalogued as rs750235068, COSV71596624; called by muse, mutect2, varscan2
- DISP3 | c.207C>G p.T69= | Silent (SNP) | VAF 202/264 reads (77%) | catalogued as COSV99606969; called by muse, mutect2, varscan2
- ERV3-1 | c.888G>T p.G296= | Silent (SNP) | VAF 44/214 reads (21%) | called by muse, mutect2, varscan2
- FSCB | c.1068A>G p.E356= | Silent (SNP) | VAF 76/198 reads (38%) | called by muse, mutect2, varscan2
- GALNT16 | c.1593G>C p.L531= | Silent (SNP) | VAF 232/567 reads (41%) | called by muse, mutect2, varscan2
- GPR135 | c.927G>T p.V309= | Silent (SNP) | VAF 61/123 reads (50%) | called by muse, mutect2, varscan2
- GPR63 | c.1251G>T p.T417= | Silent (SNP) | VAF 55/69 reads (80%) | catalogued as COSV57742835; called by muse, mutect2, varscan2
- GTF2A1 | c.510T>C p.N170= | Silent (SNP) | VAF 139/372 reads (37%) | called by muse, mutect2, varscan2
- HBS1L | c.1872G>T p.T624= | Silent (SNP) | VAF 182/220 reads (83%) | catalogued as rs753854026; called by muse, varscan2
- ITGB5 | c.906G>C p.L302= | Silent (SNP) | VAF 135/696 reads (19%) | called by muse, mutect2, varscan2
- JPH2 | c.636G>A p.A212= | Silent (SNP) | VAF 43/165 reads (26%) | catalogued as rs1251675894; called by muse, mutect2, varscan2
- KIAA0100 | c.5844A>T p.T1948= | Silent (SNP) | VAF 86/165 reads (52%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.255G>T p.V85= | Silent (SNP) | VAF 342/1220 reads (28%) | called by muse, mutect2, varscan2
- LRRC7 | c.438A>T p.P146= (on ENST00000651989 / NM_001370785.2; = p.P113= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 57/80 reads (71%) | catalogued as COSV50649265; called by muse, mutect2, varscan2
- MAPKAPK3 | c.870A>G p.T290= | Silent (SNP) | VAF 333/428 reads (78%) | called by muse, mutect2, varscan2
- MRC1 | c.108G>T p.V36= | Silent (SNP) | VAF 664/889 reads (75%) | called by muse, mutect2, varscan2
- MYH13 | c.696T>C p.F232= | Silent (SNP) | VAF 121/183 reads (66%) | called by muse, mutect2, varscan2
- NCR1 | c.129G>A p.K43= | Silent (SNP) | VAF 157/272 reads (58%) | catalogued as rs777459871; called by muse, mutect2, varscan2
- NLGN1 | c.2088C>G p.A696= | Silent (SNP) | VAF 46/373 reads (12%) | catalogued as COSV100848867, COSV64346529; called by muse, mutect2, varscan2
- NPAP1 | c.1866C>T p.S622= | Silent (SNP) | VAF 80/198 reads (40%) | catalogued as COSV61509880; called by muse, mutect2, varscan2
- NUAK2 | c.249C>T p.I83= | Silent (SNP) | VAF 86/432 reads (20%) | called by muse, mutect2, varscan2
- OR4E2 | c.639C>A p.A213= | Silent (SNP) | VAF 92/285 reads (32%) | catalogued as COSV57731449; called by muse, mutect2, varscan2
- OR5A1 | c.234T>A p.S78= | Silent (SNP) | VAF 193/266 reads (73%) | called by muse, mutect2, varscan2
- OR8J3 | c.393C>A p.L131= | Silent (SNP) | VAF 59/74 reads (80%) | called by muse, mutect2, varscan2
- PANX2 | c.48G>A p.L16= | Silent (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
- PCDHB2 | c.1506C>A p.L502= | Silent (SNP) | VAF 195/535 reads (36%) | catalogued as COSV50564243; called by muse, mutect2, varscan2
- PCDHGA2 | c.229C>T p.L77= | Silent (SNP) | VAF 40/111 reads (36%) | called by muse, mutect2, varscan2
- PDE3A | c.3348C>A p.I1116= | Silent (SNP) | VAF 213/407 reads (52%) | called by muse, varscan2
- PHACTR2 | c.1140G>T p.T380= | Silent (SNP) | VAF 160/216 reads (74%) | catalogued as rs751320429; called by muse, mutect2, varscan2
- PHF20L1 | c.1272T>A p.P424= | Silent (SNP) | VAF 175/588 reads (30%) | catalogued as COSV55198764; called by muse, mutect2, varscan2
- PIP5KL1 | c.303C>G p.A101= | Silent (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- PKHD1 | c.8691C>A p.V2897= | Silent (SNP) | VAF 309/393 reads (79%) | catalogued as COSV61860920; called by muse, mutect2, varscan2
- RFPL4A | c.300C>T p.F100= | Silent (SNP) | VAF 245/1867 reads (13%) | catalogued as rs748016056, COSV70455224; called by muse, mutect2, varscan2
- RFPL4AL1 | c.300C>T p.F100= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs775396712; called by muse, mutect2, varscan2
- ROBO4 | c.1827C>A p.P609= | Silent (SNP) | VAF 11/12 reads (92%) | called by muse, mutect2, varscan2
- SERPINA4 | c.43C>T p.L15= | Silent (SNP) | VAF 98/229 reads (43%) | called by muse, mutect2, varscan2
- SGCD | c.318C>A p.A106= (on ENST00000435422 / NM_001128209.2; = p.A107= on NM_000337.5) | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV61906555; called by muse, varscan2
- SLCO1B3 | c.1584T>C p.N528= | Silent (SNP) | VAF 75/153 reads (49%) | called by muse, varscan2
- SPATA31A6 | c.2394C>A p.A798= | Silent (SNP) | VAF 86/100 reads (86%) | called by mutect2, varscan2
- TARM1 | c.588C>A p.A196= (on ENST00000616041 / NM_001330650.1; = p.A188= on NM_001135686.3) | Silent (SNP) | VAF 1047/1453 reads (72%) | called by muse, mutect2, varscan2
- TLX3 | c.102C>G p.A34= | Silent (SNP) | VAF 85/205 reads (41%) | called by muse, mutect2, varscan2
- TPTE2 | c.1380G>A p.V460= (on ENST00000400230 / NM_199254.2; = p.V383= on NM_130785.3) | Silent (SNP) | VAF 136/286 reads (48%) | called by muse, varscan2
- TRDV2 | c.180C>G p.T60= | Silent (SNP) | VAF 186/470 reads (40%) | called by muse, varscan2
- ZNF717 | c.1062C>A p.L354= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV68863613; called by mutect2, varscan2
- AC025575.2 | n.342G>T | RNA (SNP) | VAF 77/119 reads (65%) | called by muse, mutect2, varscan2
- AC068633.1 | n.26C>A | RNA (SNP) | VAF 92/235 reads (39%) | called by muse, mutect2, varscan2
- AC133561.1 | n.1342C>G | RNA (SNP) | VAF 46/120 reads (38%) | catalogued as rs1398440000; called by mutect2, varscan2
- ALPK3 | c.-6G>A | 5'UTR (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- AMPH | c.1182+1296C>A | Intron (SNP) | VAF 75/143 reads (52%) | called by muse, mutect2, varscan2
- ANKRD33 | c.665-70G>C | Intron (SNP) | VAF 227/447 reads (51%) | called by muse, mutect2, varscan2
- APOOP5 | n.228C>T | RNA (SNP) | VAF 65/188 reads (35%) | called by muse, mutect2, varscan2
- APTX | c.-111+51G>A | Intron (SNP) | VAF 465/969 reads (48%) | called by muse, mutect2, varscan2
- ASAH1 | c.126+730G>A | Intron (SNP) | VAF 248/303 reads (82%) | called by muse, mutect2, varscan2
- ASTN1 | c.2482+36C>A | Intron (SNP) | VAF 730/840 reads (87%) | called by muse, mutect2, varscan2
- CES1P1 | n.489C>T | RNA (SNP) | VAF 206/267 reads (77%) | called by muse, mutect2, varscan2
- COMMD4 | c.142-107C>G | Intron (SNP) | VAF 60/191 reads (31%) | called by muse, mutect2, varscan2
- CSMD3 | c.7885+102C>T | Intron (SNP) | VAF 60/268 reads (22%) | catalogued as rs371163145, COSV52247749; called by muse, mutect2, varscan2
- CXCL10 | c.-7C>G | 5'UTR (SNP) | VAF 118/159 reads (74%) | called by muse, mutect2, varscan2
- CYLC1 | c.*2G>T | 3'UTR (SNP) | VAF 129/153 reads (84%) | called by muse, mutect2, varscan2
- DCAF13 | chr8:103415164 G>T | 5'Flank (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2, varscan2
- DIP2C | c.85+26602C>G | Intron (SNP) | VAF 306/385 reads (79%) | called by muse, mutect2, varscan2
- DSCR4 | n.335+21005G>T | Intron (SNP) | VAF 276/468 reads (59%) | called by muse, varscan2
- EFHC2 | c.-58delinsAG | 5'UTR (INS) | VAF 82/270 reads (30%) | called by mutect2*, pindel, varscan2*
- EGFEM1P | n.724T>A | RNA (SNP) | VAF 48/750 reads (6%) | called by muse, mutect2
- ENO2 | c.310+10G>A | Intron (SNP) | VAF 79/306 reads (26%) | called by muse, mutect2, varscan2
- FAM183BP | n.461G>T | RNA (SNP) | VAF 50/86 reads (58%) | called by muse, mutect2, varscan2
- GP2 | chr16:20327670 C>A | 5'Flank (SNP) | VAF 117/315 reads (37%) | called by muse, mutect2, varscan2
- HERC2P3 | n.2140C>T | RNA (SNP) | VAF 84/196 reads (43%) | called by mutect2, varscan2
- HSP90B1 | c.*62T>G | 3'UTR (SNP) | VAF 51/545 reads (9%) | called by muse, mutect2
- IGKV3D-15 | c.-11C>G | 5'UTR (SNP) | VAF 191/650 reads (29%) | called by muse, mutect2, varscan2
- ITPK1 | c.*809G>A | 3'UTR (SNP) | VAF 23/60 reads (38%) | catalogued as rs1339755817; called by muse, mutect2, varscan2
- KHSRP | c.2127+82G>T | Intron (SNP) | VAF 16/36 reads (44%) | catalogued as rs956299391; called by muse, mutect2, varscan2
- KRT16P2 | n.515C>G | RNA (SNP) | VAF 198/522 reads (38%) | called by muse, mutect2, varscan2
- LHCGR | c.162-1660C>A | Intron (SNP) | VAF 119/283 reads (42%) | called by muse, mutect2, varscan2
- LY6K | c.-31C>T | 5'UTR (SNP) | VAF 222/372 reads (60%) | catalogued as rs1290500736, COSV52832471; called by muse, mutect2, varscan2
- MATR3 | c.*1133A>G | 3'UTR (SNP) | VAF 171/469 reads (36%) | catalogued as rs1461950311; called by muse, mutect2, varscan2
- MIR377 | n.17C>A | RNA (SNP) | VAF 102/331 reads (31%) | called by muse, mutect2, varscan2
- MIR6511B2 | chr16:15129939 G>A | 3'Flank (SNP) | VAF 87/564 reads (15%) | catalogued as rs1157869693; called by muse, mutect2, varscan2
- MORF4 | n.480C>A | RNA (SNP) | VAF 176/229 reads (77%) | called by muse, mutect2, varscan2
- PKP3 | c.2359-72G>T | Intron (SNP) | VAF 63/89 reads (71%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.2400+1215A>G | Intron (SNP) | VAF 160/591 reads (27%) | called by muse, mutect2, varscan2
- RGS6 | c.1368+5217C>T | Intron (SNP) | VAF 146/376 reads (39%) | catalogued as rs868792549; called by muse, mutect2, varscan2
- RNU6-713P | chr12:40557177 C>A | 5'Flank (SNP) | VAF 108/215 reads (50%) | called by muse, mutect2, varscan2
- RPS27 | c.115+21A>T | Intron (SNP) | VAF 170/408 reads (42%) | catalogued as rs748421500; called by muse, mutect2, varscan2
- SPATA13 | c.-83G>T | 5'UTR (SNP) | VAF 261/350 reads (75%) | called by muse, mutect2, varscan2
- TAFA2 | c.385-10507G>T | Intron (SNP) | VAF 32/181 reads (18%) | called by muse, varscan2
- UNC13B | c.-26G>A | 5'UTR (SNP) | VAF 158/479 reads (33%) | catalogued as rs1301672160; called by muse, mutect2, varscan2
- USP22 | chr17:21043620 C>G | 5'Flank (SNP) | VAF 69/92 reads (75%) | called by muse, mutect2, varscan2
- XKR6 | c.764+76725A>T | Intron (SNP) | VAF 189/261 reads (72%) | called by muse, mutect2, varscan2
- ZC4H2 | c.*20A>T | 3'UTR (SNP) | VAF 102/114 reads (89%) | called by muse, mutect2, varscan2
- ZNF148 | c.-66A>T | 5'UTR (SNP) | VAF 79/233 reads (34%) | called by muse, mutect2, varscan2
- ZNF778 | c.*5354_*5370del | 3'UTR (DEL) | VAF 161/498 reads (32%) | called by mutect2, pindel, varscan2
